Somatic mutation profile of tumor specimen TARGET-10-PARJLF-09A (aliquot TARGET-10-PARJLF-09A-01D) from TARGET case TARGET-10-PARJLF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.8 years (3,938 days).
Specimen TARGET-10-PARJLF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5395d0a1-b5be-4f6c-9d5f-913c609fed20.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARJLF-10A (Blood Derived Normal), aliquot TARGET-10-PARJLF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/307ba329-00cd-478d-a600-c6b3f88c6590

The open-access MAF lists 21 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 4, Splice Site 1, Intron 1, Frame Shift Del 1, 5'UTR 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 33/192 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 27/63 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397507510, CD055729, CM021127, CM101143, COSV61004841, COSV61006072, COSV61006164; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CD276 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.75); catalogued as rs776412054, COSV59203320; called by muse, mutect2, varscan2
- KRT1 | c.1717G>A p.G573S | Missense Mutation (SNP) | VAF 67/134 reads (50%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.04); catalogued as rs763002437, COSV52868360; called by muse, mutect2, varscan2
- NFKBID | c.153G>T p.T51= (on ENST00000396901; = p.T203= on NM_032721.3 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 4/36 reads (11%) | catalogued as COSV61729309; called by muse, mutect2
- APC2 | c.776C>A p.T259K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.404); called by muse, mutect2
- CCDC51 | c.1009G>T p.V337L | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- CTCF | c.428_429insCC p.K144Lfs*11 | Frame Shift Ins (INS) | VAF 18/113 reads (16%) | called by mutect2, pindel, varscan2
- DLG2 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 15/174 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.158); called by muse, mutect2
- KIF5C | c.1906C>A p.H636N | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.013); called by muse, mutect2
- KMT2D | c.15950_15951del p.Y5317Ffs*27 | Frame Shift Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- PCDH18 | c.2577-1G>T p.X859_splice | Splice Site (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- PTPN11 | c.1369G>A p.V457M | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SH3KBP1 | c.548G>T p.S183I | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2
- SLAMF6 | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.187); called by muse, mutect2
- CACNG3 | c.90G>A p.T30= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs767505349, COSV50064101; called by muse, mutect2, varscan2
- DTHD1 | c.327C>A p.G109= (on ENST00000456874; = p.G234= on NM_001170700.3) | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- LAMC1 | c.3984C>A p.G1328= | Silent (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- SKIL | c.252C>T p.P84= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as COSV52061111; called by muse, mutect2, varscan2
- ANK3 | c.12596-456C>A | Intron (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2, varscan2
- SETDB2 | c.-30G>A | 5'UTR (SNP) | VAF 7/43 reads (16%) | catalogued as rs772256822; called by muse, mutect2, varscan2
